Somatic mutation profile of tumor specimen TCGA-DD-AAEH-01A (aliquot TCGA-DD-AAEH-01A-11D-A40R-10) from TCGA case TCGA-DD-AAEH, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.6 years (26,894 days).
Specimen TCGA-DD-AAEH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1759bdd-34fb-4bbe-b8b3-d0c177f74dfe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAEH-10A (Blood Derived Normal), aliquot TCGA-DD-AAEH-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc6a9a3f-7d69-4f24-9cd6-9fdd53b4a4be

The open-access MAF lists 103 somatic variants for this specimen: 77 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 24, Frame Shift Del 6, Nonsense Mutation 3, Splice Site 2, Splice Region 1, In Frame Del 1, Intron 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 46/117 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.4427C>A p.A1476D | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.609); catalogued as COSV100711742; called by muse, mutect2, varscan2
- ADAMTS13 | c.2303G>T p.R768L | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.796); catalogued as COSV100747242; called by muse, mutect2
- AFTPH | c.2457T>G p.A819= | Splice Region (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99481304; called by muse, mutect2, varscan2
- ANKRD26 | c.1126A>G p.I376V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV101066677; called by muse, mutect2, varscan2
- ANXA3 | c.15G>T p.W5C | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.677); catalogued as COSV99363989; called by muse, mutect2
- ARHGAP31 | c.2379G>C p.E793D | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV99957830; called by muse, mutect2, varscan2
- ATP8B2 | c.3457G>C p.G1153R (on ENST00000672630; = p.G1120R on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100874603; called by muse, mutect2, varscan2
- ATR | c.1732+1G>T p.X578_splice | Splice Site (SNP) | VAF 58/171 reads (34%) | catalogued as COSV100638646; called by muse, mutect2, varscan2
- C1orf158 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs140110943; called by muse, mutect2, varscan2
- CADM3 | c.700A>C p.T234P (on ENST00000368125 / NM_001127173.3; = p.T268P on NM_021189.5) | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.699); catalogued as COSV100930426; called by muse, mutect2, varscan2
- CARD11 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV101211025; called by muse, mutect2, varscan2
- CATSPER3 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV99254365; called by muse, mutect2, varscan2
- CFAP52 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.338); catalogued as COSV100235636, COSV55344774; called by muse, mutect2, varscan2
- CHRND | c.304C>G p.R102G | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99286189; called by muse, mutect2, varscan2
- COL11A2 | c.1972-2A>G p.X658_splice (on ENST00000341947 / NM_080680.3; = p.X551_splice on NM_080679.2) | Splice Site (SNP) | VAF 70/127 reads (55%) | catalogued as COSV100554311, COSV100554606; called by muse, mutect2, varscan2
- CPSF1 | c.1011C>G p.I337M | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV100574788; called by muse, mutect2, varscan2
- CRIP3 | c.407A>T p.K136M | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51485580; called by muse, mutect2, varscan2
- CRIP3 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV51485604; called by muse, mutect2, varscan2
- CTNNA2 | c.2340A>T p.Q780H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100560958, COSV100562214; called by muse, mutect2, varscan2
- CXCR3 | c.597C>A p.N199K | Missense Mutation (SNP) | VAF 55/77 reads (71%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as COSV101031698, COSV101031751; called by muse, mutect2, varscan2
- DHX15 | c.2155G>A p.V719I | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100391809, COSV61026064; called by muse, mutect2, varscan2
- DYRK1B | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.948); catalogued as COSV100546768; called by muse, mutect2, varscan2
- EPHX1 | c.1328A>C p.Q443P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV99689245; called by muse, mutect2, varscan2
- ERC2 | c.2685C>G p.D895E | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs749739992, COSV99891015; called by muse, mutect2, varscan2
- FBN1 | c.4507G>A p.V1503I | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as COSV100356531, COSV57318535; called by muse, mutect2, varscan2
- FLG | c.8324G>T p.R2775M | Missense Mutation (SNP) | VAF 50/594 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100912336; called by muse, mutect2
- FLRT2 | c.1652T>C p.V551A | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV100421115; called by muse, mutect2, varscan2
- FMN2 | c.5058G>T p.E1686D | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV100145410, COSV100147484, COSV60426905; called by muse, mutect2, varscan2
- FPR3 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.323); catalogued as rs779342164, COSV59328172; called by muse, mutect2, varscan2
- FRMPD3 | c.5126T>C p.L1709P | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99347204; called by muse, mutect2, varscan2
- GABBR1 | c.882C>A p.N294K | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100590148; called by muse, mutect2, varscan2
- GPR4 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59916543; called by muse, mutect2, varscan2
- GRAMD1B | c.407T>A p.I136N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1443514559, COSV100455319; called by muse, mutect2, varscan2
- GTPBP2 | c.863G>T p.S288I | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV100200194; called by muse, mutect2, varscan2
- HBG2 | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100400715, COSV57963324; called by muse, mutect2, varscan2
- HMCN1 | c.159T>A p.Y53* | Nonsense Mutation (SNP) | VAF 62/231 reads (27%) | catalogued as COSV99636790; called by muse, mutect2, varscan2
- HMCN1 | c.11057A>G p.D3686G | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99636794; called by muse, mutect2, varscan2
- KPRP | c.86C>A p.P29H | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV100908766, COSV100908826; called by muse, mutect2, varscan2
- LAMA3 | c.3341A>T p.Q1114L | Missense Mutation (SNP) | VAF 92/257 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV100557736; called by muse, mutect2, varscan2
- LNPK | c.1024G>T p.V342L | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99770513; called by muse, mutect2, varscan2
- LRRK2 | c.506C>A p.S169* | Nonsense Mutation (SNP) | VAF 4/58 reads (7%) | catalogued as COSV100111271; called by muse, mutect2
- MAP3K2 | c.42G>T p.L14F | Missense Mutation (SNP) | VAF 86/284 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100789407; called by muse, mutect2, varscan2
- MAP9 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100251145; called by muse, mutect2, varscan2
- MAPKAP1 | c.881T>C p.V294A | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV99785861; called by muse, mutect2, varscan2
- MRPL37 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99839219; called by muse, mutect2, varscan2
- MYO3A | c.764T>C p.L255P | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); catalogued as COSV99781832; called by muse, mutect2, varscan2
- MYO5A | c.4948A>T p.T1650S | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100698232; called by muse, mutect2, varscan2
- NEXMIF | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV99282088; called by muse, mutect2, varscan2
- NFE2L2 | c.79G>T p.D27Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960111, COSV67960209, COSV67962392; called by muse, mutect2, varscan2
- NSUN4 | c.989A>G p.N330S | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.065); catalogued as rs777733888, COSV100197700; called by muse, mutect2, varscan2
- OBSCN | c.16886T>A p.V5629E | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99485053; called by muse, mutect2, varscan2
- PALD1 | c.2321A>G p.Y774C | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99698744; called by muse, mutect2, varscan2
- PCLO | c.8246C>A p.A2749D | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100438341; called by muse, mutect2, varscan2
- PDS5B | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 135/389 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.269); catalogued as COSV100221595; called by muse, mutect2, varscan2
- PDYN | c.353A>G p.K118R | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99453407; called by muse, mutect2, varscan2
- PHRF1 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99213677; called by muse, mutect2, varscan2
- PLEKHG4 | c.1370C>A p.A457D | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.28); PolyPhen benign (0.17); catalogued as COSV64612541; called by muse, mutect2, varscan2
- PSMA1 | c.220A>G p.I74V | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs779290146, COSV101123703; called by muse, mutect2, varscan2
- RYR1 | c.4964G>T p.R1655L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.199); catalogued as COSV100617166, COSV62105166; called by muse, mutect2, varscan2
- SF3B1 | c.3412G>C p.V1138L | Missense Mutation (SNP) | VAF 91/251 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV100135065, COSV100135989; called by muse, mutect2, varscan2
- SP140 | c.643A>T p.S215C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); catalogued as COSV59454477; called by muse, mutect2, varscan2
- STON1 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV100562334; called by muse, mutect2
- SUGT1 | c.193G>T p.V65F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as COSV100139721; called by muse, mutect2, varscan2
- TANC2 | c.4042C>A p.L1348M | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101267692; called by muse, mutect2, varscan2
- TBCK | c.1792T>A p.S598T (on ENST00000273980 / NM_001163436.4; = p.S535T on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/383 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as COSV99913270; called by muse, mutect2, varscan2
- TNN | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.023); catalogued as rs757073878, COSV99512396; called by muse, mutect2, varscan2
- TUFM | c.161A>T p.Y54F | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100493236; called by muse, mutect2, varscan2
- ZNF746 | c.1174A>T p.N392Y | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV100502591; called by muse, mutect2, varscan2
- ARID2 | c.2441_2442del p.T814Sfs*26 | Frame Shift Del (DEL) | VAF 32/111 reads (29%) | called by mutect2, pindel, varscan2
- BRD7 | c.356dup p.P120Afs*43 | Frame Shift Ins (INS) | VAF 60/161 reads (37%) | called by mutect2, pindel, varscan2
- DPP7 | c.400_413del p.A134Rfs*72 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | called by mutect2, pindel, varscan2
- HNRNPA2B1 | c.931_933del p.S311del (on ENST00000354667 / NM_031243.3; = p.S299del on NM_002137.4) | In Frame Del (DEL) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- ITGAM | c.1267del p.A423Hfs*10 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | called by mutect2, pindel, varscan2
- KRTAP10-7 | c.337_338del p.V113Lfs*27 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- RTEL1 | c.1230_1245del p.S411Gfs*38 | Frame Shift Del (DEL) | VAF 17/100 reads (17%) | called by mutect2, pindel, varscan2
- ZCRB1 | c.512_513del p.I171Sfs*8 | Frame Shift Del (DEL) | VAF 39/120 reads (33%) | called by mutect2, pindel, varscan2
- ABCA13 | c.11619G>A p.L3873= | Silent (SNP) | VAF 50/144 reads (35%) | catalogued as rs370720475, COSV101447264; called by muse, mutect2, varscan2
- ABCA2 | c.5346G>A p.L1782= (on ENST00000614293; = p.L1752= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV55804159; called by muse, mutect2, varscan2
- ANK2 | c.6660G>A p.E2220= | Silent (SNP) | VAF 55/118 reads (47%) | catalogued as COSV100004531; called by muse, mutect2, varscan2
- ARHGAP45 | c.165C>T p.G55= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as rs748165428, COSV99566753; called by muse, mutect2, varscan2
- CCT3 | c.477T>C p.S159= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as COSV99827538; called by muse, mutect2, varscan2
- CSDE1 | c.1170A>G p.E390= (on ENST00000358528 / NM_001007553.3; = p.E359= on NM_007158.6) | Silent (SNP) | VAF 52/174 reads (30%) | catalogued as COSV99796159; called by muse, varscan2
- DPP10 | c.1218C>T p.I406= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV59737252; called by muse, mutect2, varscan2
- HERC1 | c.10314T>C p.N3438= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as COSV101497009; called by muse, mutect2, varscan2
- KNL1 | c.6315A>G p.Q2105= (on ENST00000346991 / NM_170589.5; = p.Q2079= on NM_144508.5) | Silent (SNP) | VAF 94/183 reads (51%) | catalogued as COSV100707135; called by muse, mutect2, varscan2
- LAMC2 | c.2202A>G p.E734= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV99918025; called by muse, mutect2
- MGAT4C | c.531G>A p.E177= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV100153472; called by muse, mutect2, varscan2
- MYO18B | c.1093T>C p.L365= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as COSV100125418; called by muse, mutect2, varscan2
- NANP | c.579C>G p.T193= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV100504969, COSV100505068; called by muse, mutect2, varscan2
- P2RY6 | c.567T>C p.Y189= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100574014; called by muse, mutect2, varscan2
- PXDN | c.4299A>G p.A1433= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as rs767295849, COSV99415175; called by muse, varscan2
- RPS3 | c.570G>T p.L190= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as COSV99584475; called by muse, mutect2, varscan2
- SLX4IP | c.468T>C p.P156= | Silent (SNP) | VAF 83/171 reads (49%) | catalogued as COSV100570938; called by muse, mutect2, varscan2
- SUCO | c.1414C>T p.L472= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV99743972; called by muse, mutect2
- TANC1 | c.2949G>A p.L983= | Silent (SNP) | VAF 25/87 reads (29%) | catalogued as COSV99715376; called by muse, mutect2, varscan2
- TOMM70 | c.360A>G p.K120= | Silent (SNP) | VAF 37/121 reads (31%) | catalogued as COSV99424635; called by muse, mutect2, varscan2
- TRIM52 | c.522C>T p.S174= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV100580792; called by muse, mutect2, varscan2
- TRO | c.3894T>C p.S1298= | Silent (SNP) | VAF 35/49 reads (71%) | catalogued as COSV99437423; called by muse, mutect2, varscan2
- WFDC3 | c.171C>T p.C57= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV99714843; called by muse, mutect2
- WNT1 | c.804G>T p.R268= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as COSV99525369; called by muse, mutect2, varscan2
- ATP9B | c.*2G>T | 3'UTR (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100304313; called by muse, mutect2, varscan2
- SMTNL1 | c.621+29_621+31del | Intron (DEL) | VAF 34/211 reads (16%) | called by pindel, varscan2
